Surgical pathology report (de-identified scan), TCGA case TCGA-HE-7130, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-7130-01A (Primary Tumor).

[page 1 of 3]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details								Histology ar
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date
	TUMOUR BUFFY	FF FF	Right kidney	RENL RENL				

[page 2 of 3]
nd staging								
Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiat ion	Pathologic al T	Pathologic al N	
█	RESECT	Right kidney	2.6	Papillary urothelial carcinoma	II	T3	NX	
	RESECT	Right kidney	2.6	Papillary urothelial carcinoma	II	T3	NX	

[page 3 of 3]
Clinical M Histology Slide URL
Comments

Source: NCI Genomic Data Commons file 6da4c052-70dc-4102-b54b-b4569cf8de6e (TCGA-HE-7130.721022F5-81B3-44E4-BFA9-5C7F1C45D711.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).